TCGA case TCGA-2G-AAGC — Testicular Germ Cell Tumors (TCGA-TGCT)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Germ Cell Neoplasms; Primary site: Testis; Tissue source site: Erasmus MC. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/1b67d80c-335e-4094-b973-e8c064c6bf59

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Netherlands; Age at index: 28 years; Year of birth: 1978; Vital status: Alive.

Diagnoses (2)
1. Mixed germ cell tumor (the primary disease): ICD-O-3 morphology code: 9085/3; ICD-10 code: C62.9; Tissue or organ of origin: Testis, NOS; Site of resection or biopsy: Testis, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 28.8 years (10,518 days); Year of diagnosis: 2007; Method of diagnosis: Orchiectomy; AJCC staging edition: 6th; AJCC clinical T: T1; AJCC clinical N: N0; AJCC clinical M: M0; AJCC clinical stage: Stage IS; AJCC pathologic T: T1; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IS; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 2,585 days (7.1 years); Ajcc serum tumor markers: S2.
   Pathology details: Intratubular germ cell neoplasia present: Yes; Lymphatic invasion present: Yes; Vascular invasion present: Yes.
   Pathology details: Lymph node dissection site: Retroperitoneal; Lymph nodes removed: Yes; Timepoint category: Prior to Adjuvant Therapy.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Bleomycin + Cisplatin + Etoposide; Treatment intent type: Adjuvant; Days to treatment start: 371 days (1.0 years); Days to treatment end: 402 days (1.1 years); Treatment outcome: Complete Response.
   Treatment given: Treatment type: Surgery, NOS; Treatment anatomic sites: Testis.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Recurrence of diagnosis 1 (Mixed germ cell tumor), site: Intra-abdominal lymph nodes. Age at diagnosis: 29.7 years (10,835 days); Days to diagnosis: 317 days; Prior treatment: Yes.

Follow-up (4 entries)
- Day 317 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Intra-abdominal lymph nodes; Days to recurrence: 317 days.
- Days to follow up: 2,216 days (6.1 years); Disease response: Tumor Free.
- Days to follow up: 2,585 days (7.1 years); Disease response: Tumor Free.
- Karnofsky performance status: 100; ECOG performance status: 0; Timepoint: Follow-up.

Molecular and laboratory tests (laboratory values one line per visit day)
- Day -4: Lactate Dehydrogenase 200; Alpha Fetoprotein 79; Human Chorionic Gonadotropin 899.
- Day 22: Lactate Dehydrogenase 354; Alpha Fetoprotein 3.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Fertility history: Did not attempt to reproduce; Undescended testis history: No.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-2G-AAGC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 210 mg.
  Slide TCGA-2G-AAGC-01A-02-TS2: Section location: Top; Percent tumor cells: 75; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 25; Percent lymphocyte infiltration: 3; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 2.
- Sample TCGA-2G-AAGC-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-2G-AAGC-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; History hypospadias: No; Tumor status: Tumor free.
- Stage record: AJCC pathologic tumor stage: IS.
- Primary pathology: Submitted tumor site: Testes; Testis tumor macroextent: Involves testis only; Intratubular germ cell neoplasm: Present; Lymphovascular invasion: Yes; Post orchi lymph node dissection: No; First treatment success: No Measureable Tumor or Tumor Markers.
- Primary pathology, Histology list, Histology 1: Histologic diagnosis: Non-Seminoma, Teratoma (Mature); Histologic diagnosis percent: 40.
- Primary pathology, Histology list, Histology 2: Histologic diagnosis: Non-Seminoma, Teratoma (Immature); Histologic diagnosis percent: 30.
- Primary pathology, Histology list, Histology 3: Histologic diagnosis: Non-Seminoma, Embryonal Carcinoma; Histologic diagnosis percent: 20.
- Primary pathology, Histology list, Histology 4: Histologic diagnosis: Non-Seminoma, Yolk Sac Tumor; Histologic diagnosis percent: 10.
- Primary pathology, Pre orchi serum marker info: Pre orchi LDH: 200; Pre orchi hcg: 899; Pre orchi afp: 79.
- Primary pathology, Post orchi serum marker info: Post orchi LDH: 354; Post orchi afp: 3.
- Primary pathology, Molecular test result list: Molecular test result: Lactate Dehydrogenase (LDH) - Normal; Molecular test result: Human Chorionic Gonadotropin (HCG) - Normal; Molecular test result: Alpha Fetaprotein (AFP) - Normal.
- Follow-up form 1: Lost to follow-up: No; Post orchi lymph node dissection: Yes - Prior to chemotherapy; Tumor status: Tumor free; Treatment outcome first course: Complete Remission/Response.
- Follow-up form 2: Lost to follow-up: No; Post orchi lymph node dissection: Yes - Prior to chemotherapy; Tumor status: Tumor free; Treatment outcome first course: No Measureable Tumor or Tumor Markers.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 2,585 days; disease-specific survival: no event (censored), 2,585 days; disease-free interval: event (new tumor event after initially disease-free), 317 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 317 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-2G-AAGC-01A-21D-A42X-01): tumor purity 0.66, ploidy 2.99, whole-genome doublings 1.
